Somatic mutation profile of tumor specimen BA2385D (aliquot aq-BA2385D) from BEATAML1.0 case 2277, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Chronic myelomonocytic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 81.4 years (29,727 days).
Specimen BA2385D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eca0d32c-98a1-47be-885c-9c60e774c240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2297D (Solid Tissue Normal), aliquot aq-BA2297D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/920ce50a-6fa8-466c-8c60-abed3d19cb30

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.29C>A p.A10E | Missense Mutation (SNP) | VAF 3/52 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as rs1217714114; called by muse, mutect2
- HYDIN | c.6739G>A p.A2247T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs372754655; called by muse, mutect2, varscan2
- ATP8A2 | c.1059C>A p.D353E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- FAM83F | c.750C>G p.D250E | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NOC3L | c.366G>T p.A122= | Silent (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- UBN1 | c.2487C>A p.G829= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
